Somatic mutation profile of tumor specimen MMRF_1434_1_BM_CD138pos (aliquot MMRF_1434_1_BM_CD138pos_T1_KAS5U_L01378) from MMRF case MMRF_1434, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 61.8 years (22,582 days).
Specimen MMRF_1434_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 296026db-8122-4485-a998-9354158b9123.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1434_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1434_1_PB_Whole_C2_KAS5U_L01390; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9944098c-781f-4d5f-bcf4-42293291699e

The open-access MAF lists 94 somatic variants for this specimen: 39 protein-altering or splice-affecting, 11 silent, 44 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, 3'UTR 22, Intron 14, Silent 11, 5'UTR 3, 3'Flank 2, Nonsense Mutation 2, 5'Flank 2, Splice Region 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 46/61 reads (75%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- BCOR | c.4753G>T p.D1585Y (on ENST00000378444 / NM_001123385.2; = p.D1551Y on NM_017745.6) | Missense Mutation (SNP) | VAF 48/105 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60722513; called by muse, mutect2, varscan2
- CSRNP3 | c.1063G>A p.G355R | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.269); catalogued as rs139133187; called by muse, mutect2, varscan2
- DUSP2 | c.378C>G p.Y126* | Nonsense Mutation (SNP) | VAF 31/83 reads (37%) | catalogued as rs1364514451, COSV56619695; called by muse, mutect2, varscan2
- EPHA3 | c.1447A>C p.S483R | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV60721586; called by muse, mutect2, varscan2
- IGHV1-69D | c.161G>A p.S54N | Missense Mutation (SNP) | VAF 52/146 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs1378343210; called by muse, varscan2
- IGHV2-70 | c.151A>T p.S51C | Missense Mutation (SNP) | VAF 52/105 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.368); catalogued as rs376400758; called by muse, mutect2, varscan2
- IGHV2-70D | c.305C>G p.T102R | Missense Mutation (SNP) | VAF 26/32 reads (81%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as rs1310540287; called by muse, varscan2
- IGKV1-8 | c.155A>T p.Y52F | Missense Mutation (SNP) | VAF 87/201 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.02); catalogued as rs774181740; called by muse, mutect2, varscan2
- IGKV2-24 | c.328G>A p.V110I | Missense Mutation (SNP) | VAF 61/127 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.057); catalogued as rs536039015; called by muse, mutect2, varscan2
- IGKV4-1 | c.172T>G p.Y58D | Missense Mutation (SNP) | VAF 56/58 reads (97%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); catalogued as rs7606636; called by muse, mutect2, varscan2
- LRIF1 | c.68+8C>T | Splice Region (SNP) | VAF 48/79 reads (61%) | catalogued as rs567649877; called by muse, mutect2, varscan2
- MARVELD3 | c.919G>A p.G307S | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.066); catalogued as rs773517243; called by muse, mutect2, varscan2
- NKAP | c.1103G>T p.R368L | Missense Mutation (SNP) | VAF 9/222 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV57631113; called by muse, mutect2
- OR8K1 | c.75C>A p.D25E | Missense Mutation (SNP) | VAF 88/163 reads (54%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.013); catalogued as rs769004561, COSV54401922; called by muse, mutect2, varscan2
- PRR12 | c.1144C>T p.R382W (on ENST00000615927; = p.R1203W on NM_020719.3) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as rs1427520314; called by muse, mutect2, varscan2
- RUSC2 | c.3614C>T p.T1205M | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781091436, COSV63428186; called by muse, mutect2, varscan2
- STOX2 | c.577C>T p.R193* | Nonsense Mutation (SNP) | VAF 145/349 reads (42%) | catalogued as rs746637070; called by muse, mutect2, varscan2
- CARMIL1 | c.759G>T p.L253F | Missense Mutation (SNP) | VAF 90/213 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCND1 | c.105G>T p.E35D | Missense Mutation (SNP) | VAF 60/148 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, varscan2
- COL16A1 | c.2231C>A p.P744H | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- HIVEP1 | c.7366G>A p.G2456R | Missense Mutation (SNP) | VAF 61/111 reads (55%) | SIFT tolerated (0.05); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- IGHV1-69D | c.326A>G p.D109G | Missense Mutation (SNP) | VAF 59/178 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- IGHV1-69D | c.295T>A p.Y99N | Missense Mutation (SNP) | VAF 68/248 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, varscan2
- IGHV1-69D | c.268A>G p.T90A | Missense Mutation (SNP) | VAF 92/274 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.177); called by muse, varscan2
- IGHV1-69D | c.260T>C p.V87A | Missense Mutation (SNP) | VAF 66/260 reads (25%) | SIFT tolerated (0.63); PolyPhen benign (0.043); called by muse, varscan2
- IGHV1-69D | c.224G>A p.G75D | Missense Mutation (SNP) | VAF 80/228 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.023); called by muse, varscan2
- IGHV2-70D | c.65C>G p.T22S | Missense Mutation (SNP) | VAF 42/46 reads (91%) | SIFT deleterious (0.02); PolyPhen benign (0.042); called by muse, varscan2
- KCNB1 | c.1080G>C p.K360N | Missense Mutation (SNP) | VAF 7/130 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2
- KIF5B | c.85T>A p.Y29N | Missense Mutation (SNP) | VAF 6/105 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.011); called by muse, mutect2
- LRRC7 | c.4276C>T p.H1426Y (on ENST00000651989 / NM_001370785.2; = p.H1346Y on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- NFYC | c.430T>A p.Y144N | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- PHKA1 | c.1078A>G p.I360V | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- PIH1D2 | c.718G>A p.V240M | Missense Mutation (SNP) | VAF 52/133 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- RPS6KA2 | c.1780A>T p.I594F | Missense Mutation (SNP) | VAF 80/181 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.415); called by muse, mutect2, varscan2
- SETD2 | c.1744del p.I582Sfs*19 | Frame Shift Del (DEL) | VAF 47/126 reads (37%) | called by mutect2, pindel, varscan2
- TNFRSF1A | c.1073C>T p.T358M | Missense Mutation (SNP) | VAF 45/59 reads (76%) | SIFT tolerated (0.46); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- TUBGCP6 | c.3862C>T p.P1288S | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- UTP20 | c.6455C>T p.A2152V | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ADAMTSL2 | c.954C>T p.N318= | Silent (SNP) | VAF 41/65 reads (63%) | catalogued as rs886063638; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DCHS1 | c.7887T>A p.A2629= | Silent (SNP) | VAF 42/124 reads (34%) | called by muse, mutect2, varscan2
- DIS3 | c.199C>T p.L67= | Silent (SNP) | VAF 11/16 reads (69%) | called by muse, mutect2, varscan2
- FRMD4A | c.2892G>A p.Q964= | Silent (SNP) | VAF 12/20 reads (60%) | catalogued as rs748898441; called by muse, varscan2
- GK2 | c.408C>T p.F136= | Silent (SNP) | VAF 40/76 reads (53%) | catalogued as COSV62626859; called by muse, mutect2, varscan2
- HMCN2 | c.9558C>G p.G3186= | Silent (SNP) | VAF 30/53 reads (57%) | catalogued as rs932386204; called by muse, mutect2, varscan2
- KCNC4 | c.456C>T p.R152= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as COSV63925812; called by muse, mutect2, varscan2
- PFKL | c.1950C>T p.V650= | Silent (SNP) | VAF 65/121 reads (54%) | called by muse, mutect2, varscan2
- PREX2 | c.2436G>C p.V812= | Silent (SNP) | VAF 39/108 reads (36%) | called by muse, mutect2, varscan2
- RPL10 | c.285C>T p.H95= | Silent (SNP) | VAF 30/58 reads (52%) | catalogued as rs11558108; called by muse, mutect2, varscan2
- ZNF592 | c.120C>T p.P40= | Silent (SNP) | VAF 46/130 reads (35%) | called by muse, mutect2, varscan2
- AKAP13 | c.478+1561T>C | Intron (SNP) | VAF 22/71 reads (31%) | called by muse, mutect2, varscan2
- BCAS3 | c.2639-3349del | Intron (DEL) | VAF 50/120 reads (42%) | catalogued as rs756350876, COSV66772038; called by mutect2, varscan2
- BCL7A | chr12:122021445 C>T | 5'Flank (SNP) | VAF 51/101 reads (50%) | catalogued as COSV55846302, COSV55847851, COSV55851309; called by muse, mutect2, varscan2
- C5orf47 | c.-85C>T | 5'UTR (SNP) | VAF 13/34 reads (38%) | catalogued as rs1277222615; called by muse, mutect2, varscan2
- CCND1 | c.-4A>G | 5'UTR (SNP) | VAF 19/39 reads (49%) | catalogued as rs1379943115; called by muse, mutect2, varscan2
- CLIP1 | c.3966+976C>T | Intron (SNP) | VAF 3/43 reads (7%) | catalogued as rs1188038858; called by muse, mutect2
- CSNK1D | c.886-431G>A | Intron (SNP) | VAF 6/11 reads (55%) | catalogued as rs991691151; called by muse, mutect2, varscan2
- DCAF4L2 | c.*455G>A | 3'UTR (SNP) | VAF 71/159 reads (45%) | called by muse, mutect2, varscan2
- DNM1L | c.251-1413dup | Intron (INS) | VAF 30/46 reads (65%) | catalogued as rs750339400; called by mutect2, varscan2
- FCRL5 | c.1681+1144dup | Intron (INS) | VAF 46/116 reads (40%) | called by mutect2, varscan2
- FCRLB | c.*154C>T | 3'UTR (SNP) | VAF 47/139 reads (34%) | called by muse, mutect2, varscan2
- FCRLB | c.*155C>T | 3'UTR (SNP) | VAF 47/138 reads (34%) | called by muse, mutect2, varscan2
- FLNB | c.6368-539G>A | Intron (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- FOXK1 | c.*5095G>A | 3'UTR (SNP) | VAF 39/84 reads (46%) | called by muse, mutect2, varscan2
- GABRB2 | c.*2441T>C | 3'UTR (SNP) | VAF 44/98 reads (45%) | called by muse, mutect2, varscan2
- GON4L | chr1:155748404 T>C | 3'Flank (SNP) | VAF 8/23 reads (35%) | catalogued as rs1008994723; called by muse, mutect2, varscan2
- IFNAR1 | c.*1257C>T | 3'UTR (SNP) | VAF 5/75 reads (7%) | called by muse, mutect2
- IFT46 | c.-35-428C>T | Intron (SNP) | VAF 4/25 reads (16%) | catalogued as rs1370319451; called by muse, mutect2
- IGLL5 | c.-90C>G | 5'UTR (SNP) | VAF 50/85 reads (59%) | catalogued as COSV73251269; called by muse, mutect2, varscan2
- KBTBD12 | c.*3248G>T | 3'UTR (SNP) | VAF 43/85 reads (51%) | called by muse, mutect2, varscan2
- KLF3 | c.*93A>T | 3'UTR (SNP) | VAF 197/411 reads (48%) | called by muse, mutect2, varscan2
- LASP1 | c.*2132A>T | 3'UTR (SNP) | VAF 14/60 reads (23%) | called by muse, mutect2, varscan2
- LIMCH1 | c.486+3487A>C | Intron (SNP) | VAF 25/53 reads (47%) | called by muse, mutect2, varscan2
- LONP2 | c.*242T>A | 3'UTR (SNP) | VAF 41/99 reads (41%) | called by muse, mutect2, varscan2
- MBP | c.576+54A>G | Intron (SNP) | VAF 197/421 reads (47%) | called by muse, mutect2, varscan2
- MEIS3 | c.448-48G>A | Intron (SNP) | VAF 17/47 reads (36%) | catalogued as rs752732950, COSV58983570; called by muse, mutect2, varscan2
- MGST3 | c.-7-35C>A | Intron (SNP) | VAF 116/228 reads (51%) | called by muse, mutect2, varscan2
- NLGN1 | c.*1836del | 3'UTR (DEL) | VAF 26/62 reads (42%) | catalogued as rs886951308; called by mutect2, varscan2
- NPVF | c.*221del | 3'UTR (DEL) | VAF 38/76 reads (50%) | catalogued as rs200857217; called by mutect2, varscan2
- PERP | c.*106T>G | 3'UTR (SNP) | VAF 135/279 reads (48%) | called by muse, mutect2, varscan2
- PIGX | c.*2026T>C | 3'UTR (SNP) | VAF 26/63 reads (41%) | called by muse, mutect2, varscan2
- POLR3E | c.282-119C>T | Intron (SNP) | VAF 17/40 reads (43%) | catalogued as rs1343901762; called by muse, mutect2, varscan2
- PRRG3 | c.*248C>A | 3'UTR (SNP) | VAF 48/108 reads (44%) | called by muse, mutect2, varscan2
- PTS | chr11:112226412 G>A | 5'Flank (SNP) | VAF 13/28 reads (46%) | catalogued as rs1353916390; called by muse, mutect2, varscan2
- RANBP2 | c.*1146A>T | 3'UTR (SNP) | VAF 58/116 reads (50%) | called by muse, mutect2, varscan2
- SLC39A14 | chr8:22420430 G>A | 3'Flank (SNP) | VAF 45/92 reads (49%) | called by muse, mutect2, varscan2
- SLC66A1L | n.294G>T | RNA (SNP) | VAF 64/129 reads (50%) | called by muse, mutect2, varscan2
- SLITRK4 | c.*5521C>A | 3'UTR (SNP) | VAF 35/75 reads (47%) | called by muse, mutect2, varscan2
- TEF | c.*1811C>T | 3'UTR (SNP) | VAF 32/77 reads (42%) | catalogued as rs149617949; called by muse, mutect2, varscan2
- TP63 | c.*2068A>T | 3'UTR (SNP) | VAF 27/67 reads (40%) | called by muse, mutect2, varscan2
- TTC12 | c.445-23A>T | Intron (SNP) | VAF 38/88 reads (43%) | called by muse, mutect2, varscan2
- VPS13A | c.*4165C>T | 3'UTR (SNP) | VAF 47/145 reads (32%) | catalogued as rs889419880; called by muse, mutect2, varscan2
- YAP1 | c.*2442G>A | 3'UTR (SNP) | VAF 85/155 reads (55%) | called by muse, mutect2, varscan2
- YIPF4 | c.*5051A>T | 3'UTR (SNP) | VAF 13/32 reads (41%) | called by muse, mutect2, varscan2
